Somatic mutation profile of tumor specimen C3N-02374-01 (aliquot CPT0146380010) from CPTAC case C3N-02374, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 67.5 years (24,670 days).
Specimen C3N-02374-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4c4b17ac-df46-4ed4-ab15-856357ff5e9e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02374-71 (Blood Derived Normal), aliquot CPT0146410002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2f20d44a-071f-4f64-a747-78c6d18d7b2f

The open-access MAF lists 305 somatic variants for this specimen: 212 protein-altering or splice-affecting, 55 silent, 38 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 178, Silent 55, Intron 19, Nonsense Mutation 18, 3'UTR 6, Frame Shift Del 5, Splice Region 5, 5'Flank 5, RNA 4, Splice Site 4, 5'UTR 2, 3'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 143/504 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.1015G>T p.E339* | Nonsense Mutation (SNP) | VAF 106/353 reads (30%) | catalogued as rs17882252, CM984588, COSV52705645, COSV52980241, COSV53040770, COSV53664260; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAMTS3 | c.298C>G p.Q100E | Missense Mutation (SNP) | VAF 24/168 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.05); catalogued as COSV54383428; called by muse, mutect2, varscan2
- ADGRL2 | c.3267del p.V1091Yfs*27 (on ENST00000370717 / NM_001366005.1; = p.V1078Yfs*27 on NM_012302.4) | Frame Shift Del (DEL) | VAF 20/82 reads (24%) | catalogued as COSV54683332; called by mutect2, pindel, varscan2
- ALG1 | c.728C>T p.P243L | Missense Mutation (SNP) | VAF 146/962 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs570334955, COSV52159264; called by muse, mutect2, varscan2
- BCL2L12 | c.46G>A p.G16S | Missense Mutation (SNP) | VAF 49/211 reads (23%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.01); catalogued as COSV55864101; called by muse, mutect2, varscan2
- CALR | c.974C>A p.T325N | Missense Mutation (SNP) | VAF 41/353 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV57119714; called by muse, varscan2
- CD2BP2 | c.775G>A p.E259K | Missense Mutation (SNP) | VAF 47/184 reads (26%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as rs1285570284; called by muse, mutect2, varscan2
- CFAP54 | c.5014C>G p.L1672V | Missense Mutation (SNP) | VAF 9/132 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.036); catalogued as COSV100733187; called by muse, mutect2
- CHRM3 | c.1759G>C p.E587Q | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.001); catalogued as COSV55101946; called by muse, mutect2, varscan2
- CMTM5 | c.376C>G p.P126A | Missense Mutation (SNP) | VAF 91/448 reads (20%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.005); catalogued as rs778322928; called by mutect2, varscan2
- CNTN6 | c.1304C>A p.A435D | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63162721; called by muse, mutect2
- COL11A1 | c.4273G>T p.A1425S | Missense Mutation (SNP) | VAF 29/151 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.019); catalogued as COSV62184054; called by muse, mutect2, varscan2
- COL4A1 | c.1583G>T p.G528V | Missense Mutation (SNP) | VAF 57/282 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM076125; called by muse, mutect2, varscan2
- CSMD3 | c.8654G>C p.R2885T (on ENST00000297405 / NM_001363185.1; = p.R2716T on NM_052900.3) | Missense Mutation (SNP) | VAF 24/444 reads (5%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.996); catalogued as COSV52339922; called by muse, mutect2
- CTNNA2 | c.2002G>T p.A668S | Missense Mutation (SNP) | VAF 21/177 reads (12%) | SIFT tolerated (0.8); PolyPhen benign (0.173); catalogued as COSV58163403; called by muse, mutect2, varscan2
- CTNND2 | c.334G>C p.D112H | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV58864324; called by muse, mutect2, varscan2
- CUBN | c.9964G>T p.V3322L | Missense Mutation (SNP) | VAF 85/345 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.458); catalogued as COSV64712842; called by muse, mutect2, varscan2
- CXXC1 | c.1813C>T p.R605C | Missense Mutation (SNP) | VAF 26/169 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV53275441; called by muse, mutect2, varscan2
- DGKB | c.1085C>T p.P362L | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0.034); catalogued as rs373262401, COSV51820604; called by muse, mutect2, varscan2
- DKK2 | c.263G>A p.R88K | Missense Mutation (SNP) | VAF 23/209 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV53393361; called by muse, mutect2, varscan2
- DNAH5 | c.2936A>T p.E979V | Missense Mutation (SNP) | VAF 59/321 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.288); catalogued as COSV54239503; called by muse, mutect2, varscan2
- DNAJC28 | c.802G>C p.E268Q | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.327); catalogued as COSV58721673; called by muse, varscan2
- DPPA4 | c.221G>T p.R74I | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.758); catalogued as COSV59510093; called by muse, mutect2
- EPHB6 | c.1991G>T p.R664L | Missense Mutation (SNP) | VAF 180/537 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV63892581, COSV63894024; called by muse, mutect2, varscan2
- ERICH3 | c.2783C>G p.S928W | Missense Mutation (SNP) | VAF 68/243 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as rs754456981, COSV58605032; called by muse, mutect2, varscan2
- ESRRB | c.1247A>T p.Q416L | Missense Mutation (SNP) | VAF 128/721 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.348); catalogued as COSV99835662; called by muse, mutect2, varscan2
- FLT3 | c.565G>A p.V189I | Missense Mutation (SNP) | VAF 13/182 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs142392340; called by muse, mutect2
- FSCN3 | c.1297G>T p.G433W | Missense Mutation (SNP) | VAF 35/111 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as rs1348128334, COSV99757148; called by muse, mutect2, varscan2
- GFPT2 | c.1372G>C p.E458Q | Missense Mutation (SNP) | VAF 64/453 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.368); catalogued as rs1422272689; called by muse, mutect2, varscan2
- GLG1 | c.2021T>C p.I674T | Missense Mutation (SNP) | VAF 17/230 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.281); catalogued as rs368450618; called by muse, mutect2
- GOPC | c.1086G>T p.E362D | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0.017); catalogued as COSV50003105; called by muse, mutect2
- GRXCR1 | c.370A>T p.T124S | Missense Mutation (SNP) | VAF 8/172 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101295750; called by muse, mutect2
- HSP90AA1 | c.306C>A p.S102R | Missense Mutation (SNP) | VAF 115/483 reads (24%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.005); catalogued as COSV100593187; called by muse, mutect2, varscan2
- HTR6 | c.1112C>T p.P371L | Missense Mutation (SNP) | VAF 50/667 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.122); catalogued as rs764518966; called by muse, mutect2
- KIAA1109 | c.1858A>G p.T620A | Missense Mutation (SNP) | VAF 37/150 reads (25%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV99150148; called by muse, mutect2, varscan2
- KLHL1 | c.1466C>A p.A489E | Missense Mutation (SNP) | VAF 15/152 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); catalogued as COSV64778732, COSV64782108; called by muse, mutect2, varscan2
- KRTAP6-3 | c.290G>A p.R97K | Missense Mutation (SNP) | VAF 32/221 reads (14%) | PolyPhen benign (0.029); catalogued as rs113124062; called by muse, mutect2, varscan2
- LAMA1 | c.1862C>T p.T621I | Missense Mutation (SNP) | VAF 37/176 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs1372291355, COSV67539196; called by muse, mutect2, varscan2
- LRFN2 | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 48/609 reads (8%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.564); catalogued as rs1387751774, COSV57833497; called by muse, mutect2
- MLH3 | c.1408A>G p.M470V | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs1440764823; called by muse, mutect2, varscan2
- MROH2B | c.3155C>A p.T1052K | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.031); catalogued as rs993601040, COSV101270590; called by mutect2, varscan2
- MRPL50 | c.382G>C p.D128H | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.018); catalogued as rs1422901425; called by muse, mutect2
- MRPS12 | c.318G>C p.Q106H | Missense Mutation (SNP) | VAF 53/345 reads (15%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV55502055; called by muse, mutect2, varscan2
- MTHFSD | c.16+8G>T | Splice Region (SNP) | VAF 55/200 reads (28%) | catalogued as rs374118014; called by muse, mutect2, varscan2
- NAV3 | c.3148A>G p.K1050E | Missense Mutation (SNP) | VAF 31/266 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs745747468; called by muse, mutect2, varscan2
- NDFIP2 | c.163G>A p.G55S | Missense Mutation (SNP) | VAF 179/485 reads (37%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.005); catalogued as rs1284114009; called by muse, mutect2, varscan2
- NOS1 | c.2546G>C p.R849P | Missense Mutation (SNP) | VAF 60/208 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57613241; called by muse, mutect2, varscan2
- NRXN1 | c.2438G>A p.R813H | Missense Mutation (SNP) | VAF 18/156 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); catalogued as rs773464948, COSV58455452; called by muse, mutect2, varscan2
- ODAPH | c.244C>A p.H82N | Missense Mutation (SNP) | VAF 44/558 reads (8%) | SIFT tolerated (0.44); PolyPhen benign (0.031); catalogued as COSV61141033; called by muse, mutect2
- OR7C2 | c.867C>G p.Y289* | Nonsense Mutation (SNP) | VAF 62/265 reads (23%) | catalogued as COSV50181676; called by muse, mutect2, varscan2
- PCDHA1 | c.859C>T p.R287C | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.231); catalogued as rs144952734; called by muse, mutect2, varscan2
- PCK1 | c.1095C>A p.D365E | Missense Mutation (SNP) | VAF 135/598 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.093); catalogued as COSV60128382; called by muse, mutect2, varscan2
- PKLR | c.346C>T p.R116* | Nonsense Mutation (SNP) | VAF 68/854 reads (8%) | catalogued as rs971962553, COSV61360923; called by muse, mutect2
- PLXND1 | c.2738G>A p.G913E | Missense Mutation (SNP) | VAF 36/441 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs986929788; called by muse, mutect2
- PPP1R27 | c.76G>A p.V26M | Missense Mutation (SNP) | VAF 21/242 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs780458528, COSV57672562; called by muse, mutect2
- PTER | c.640C>T p.R214* | Nonsense Mutation (SNP) | VAF 12/198 reads (6%) | catalogued as rs370033967; called by muse, mutect2
- RBM27 | c.1825C>T p.Q609* | Nonsense Mutation (SNP) | VAF 8/51 reads (16%) | catalogued as COSV54592227; called by muse, mutect2, varscan2
- RYR1 | c.5278C>T p.H1760Y | Missense Mutation (SNP) | VAF 267/789 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.579); catalogued as rs752505416, COSV62096019; called by muse, mutect2, varscan2
- RYR1 | c.10240C>T p.R3414C | Missense Mutation (SNP) | VAF 68/448 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs148892609; called by muse, mutect2, varscan2
- SDC3 | c.1061C>T p.A354V | Missense Mutation (SNP) | VAF 134/436 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.138); catalogued as rs761708005; called by muse, mutect2, varscan2
- SEMA6B | c.1001C>T p.S334L | Missense Mutation (SNP) | VAF 20/247 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752131703, COSV100014732; called by muse, mutect2
- SH3TC2 | c.1973G>A p.R658H | Missense Mutation (SNP) | VAF 64/633 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0.36); catalogued as rs138040787; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC37A1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 47/421 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as rs1239265740; called by muse, mutect2, varscan2
- SLC44A4 | c.1282G>A p.G428S | Missense Mutation (SNP) | VAF 52/331 reads (16%) | SIFT tolerated (0.52); PolyPhen benign (0.009); catalogued as COSV57666941; called by muse, mutect2, varscan2
- SLC52A2 | c.656C>T p.P219L | Missense Mutation (SNP) | VAF 148/997 reads (15%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.92); catalogued as rs374006728; ClinVar: uncertain significance; called by mutect2, varscan2
- SLC6A4 | c.116A>G p.E39G | Missense Mutation (SNP) | VAF 67/430 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs752079357; called by muse, mutect2, varscan2
- SLITRK3 | c.323T>A p.L108H | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53854366; called by muse, mutect2, varscan2
- SPATA31E1 | c.391G>A p.E131K | Missense Mutation (SNP) | VAF 79/360 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.391); catalogued as rs1346908774; called by muse, mutect2, varscan2
- ST7 | c.286G>A p.V96I | Missense Mutation (SNP) | VAF 16/141 reads (11%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.576); catalogued as rs1477490131; called by muse, mutect2, varscan2
- STARD13 | c.2293G>C p.E765Q (on ENST00000336934 / NM_001243476.3; = p.E647Q on NM_052851.3) | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.882); catalogued as rs1392547164; called by muse, mutect2
- TCEAL5 | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 76/153 reads (50%) | SIFT tolerated (0.22); PolyPhen benign (0.329); catalogued as COSV101013095; called by muse, mutect2, varscan2
- TCF7L2 | c.301C>G p.P101A | Missense Mutation (SNP) | VAF 46/253 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.07); catalogued as COSV60503517; called by muse, mutect2, varscan2
- TET2 | c.1842del p.L615Sfs*24 | Frame Shift Del (DEL) | VAF 29/170 reads (17%) | catalogued as rs763386429; called by mutect2, varscan2
- THEG | c.1051G>T p.G351* | Nonsense Mutation (SNP) | VAF 13/86 reads (15%) | catalogued as COSV61075114; called by muse, mutect2, varscan2
- TMC3 | c.142G>T p.E48* | Nonsense Mutation (SNP) | VAF 41/152 reads (27%) | catalogued as COSV63922660; called by muse, mutect2, varscan2
- TMEM199 | c.556G>A p.A186T | Missense Mutation (SNP) | VAF 39/363 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782624450, COSV50228188; called by muse, mutect2, varscan2
- TNKS | c.401C>A p.S134Y | Missense Mutation (SNP) | VAF 348/774 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.248); catalogued as COSV60054598; called by muse, mutect2, varscan2
- TOM1 | c.51C>A p.I17= | Splice Region (SNP) | VAF 108/567 reads (19%) | catalogued as COSV53334740; called by muse, mutect2, varscan2
- TRRAP | c.7729A>G p.K2577E (on ENST00000359863 / NM_001244580.1; = p.K2559E on NM_003496.3) | Missense Mutation (SNP) | VAF 92/232 reads (40%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs1357296242; called by muse, mutect2, varscan2
- USH2A | c.3794C>T p.P1265L | Missense Mutation (SNP) | VAF 29/137 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); catalogued as rs1282426752, COSV56357152; called by muse, mutect2, varscan2
- XIRP2 | c.3973G>A p.D1325N (on ENST00000628543; = p.D1500N on NM_152381.6) | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs958465056, COSV54706385; called by muse, mutect2
- ZNF462 | c.2680G>A p.D894N | Missense Mutation (SNP) | VAF 70/312 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); catalogued as rs776022280, COSV99473760; called by muse, mutect2, varscan2
- ZNF835 | c.198C>A p.S66R | Missense Mutation (SNP) | VAF 243/580 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0.02); catalogued as rs764979088; called by mutect2, varscan2
- ABCC1 | c.1919del p.G640Afs*7 | Frame Shift Del (DEL) | VAF 58/369 reads (16%) | called by mutect2, pindel, varscan2
- ABCC11 | c.2251A>T p.K751* | Nonsense Mutation (SNP) | VAF 101/359 reads (28%) | called by muse, mutect2, varscan2
- ACAP2 | c.1321C>T p.H441Y | Missense Mutation (SNP) | VAF 65/227 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ACOX1 | c.403A>G p.T135A | Missense Mutation (SNP) | VAF 70/471 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- ADCY1 | c.1168G>T p.E390* | Nonsense Mutation (SNP) | VAF 46/311 reads (15%) | called by muse, mutect2, varscan2
- ADGRL1 | c.2981+1G>A p.X994_splice (on ENST00000340736 / NM_001008701.3; = p.X989_splice on NM_014921.5) | Splice Site (SNP) | VAF 26/269 reads (10%) | called by muse, mutect2
- ANO1 | c.2036T>A p.F679Y | Missense Mutation (SNP) | VAF 11/214 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- ARID2 | c.1580+2T>G p.X527_splice | Splice Site (SNP) | VAF 31/99 reads (31%) | called by muse, mutect2, varscan2
- ART3 | c.283G>A p.G95R | Missense Mutation (SNP) | VAF 44/150 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATP1A3 | c.68C>A p.S23* (on ENST00000545399 / NM_001256214.2; = p.S10* on NM_152296.5) | Nonsense Mutation (SNP) | VAF 33/558 reads (6%) | called by muse, mutect2
- ATP7B | c.1717A>C p.M573L | Missense Mutation (SNP) | VAF 54/263 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- BEND3 | c.1640A>C p.E547A | Missense Mutation (SNP) | VAF 151/386 reads (39%) | SIFT tolerated (0.25); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- BRD3 | c.1444C>G p.Q482E | Missense Mutation (SNP) | VAF 12/398 reads (3%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.899); called by muse, mutect2
- C8orf34 | c.416G>T p.G139V | Missense Mutation (SNP) | VAF 26/201 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- CCDC134 | c.411C>A p.N137K | Missense Mutation (SNP) | VAF 89/434 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- CCSER1 | c.1406G>A p.G469E | Missense Mutation (SNP) | VAF 34/172 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CD163L1 | c.3722C>A p.T1241K | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CD180 | c.771C>A p.D257E | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- CDH9 | c.2259G>T p.L753F | Missense Mutation (SNP) | VAF 18/147 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CNOT3 | c.1068G>T p.K356N | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.41); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- COL11A1 | c.2977C>A p.P993T | Missense Mutation (SNP) | VAF 31/357 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- COL13A1 | c.329C>A p.A110D | Missense Mutation (SNP) | VAF 45/154 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- COL1A2 | c.3883T>A p.S1295T | Missense Mutation (SNP) | VAF 123/303 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- COL4A2 | c.2998G>T p.G1000W | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL5A1 | c.4541C>G p.P1514R | Missense Mutation (SNP) | VAF 44/572 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.624); called by muse, mutect2
- COPA | c.1443-3C>G | Splice Region (SNP) | VAF 34/82 reads (41%) | called by muse, mutect2, varscan2
- COPG2 | c.502A>G p.K168E | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- CSHL1 | c.252C>A p.C84* | Nonsense Mutation (SNP) | VAF 38/530 reads (7%) | called by muse, mutect2
- CSNK1G1 | c.95C>T p.S32L | Missense Mutation (SNP) | VAF 39/282 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- CT47B1 | c.447C>A p.S149R | Missense Mutation (SNP) | VAF 249/407 reads (61%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- DCHS1 | c.7378C>G p.P2460A | Missense Mutation (SNP) | VAF 34/434 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- DCHS1 | c.6958G>A p.D2320N | Missense Mutation (SNP) | VAF 79/144 reads (55%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- DNAH11 | c.8743G>T p.A2915S | Missense Mutation (SNP) | VAF 26/172 reads (15%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- DNAH8 | c.11365G>T p.A3789S | Missense Mutation (SNP) | VAF 29/214 reads (14%) | SIFT tolerated (0.69); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- DOCK5 | c.2757T>C p.G919= | Splice Region (SNP) | VAF 24/194 reads (12%) | called by muse, mutect2, varscan2
- DSCAM | c.542T>A p.L181* | Nonsense Mutation (SNP) | VAF 11/93 reads (12%) | called by muse, mutect2, varscan2
- EDRF1 | c.2371+3G>A | Splice Region (SNP) | VAF 14/151 reads (9%) | called by muse, mutect2
- ELAPOR2 | c.296G>T p.R99I | Missense Mutation (SNP) | VAF 40/296 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- ELOVL4 | c.803G>C p.R268P | Missense Mutation (SNP) | VAF 25/214 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- EN1 | c.376C>T p.L126F | Missense Mutation (SNP) | VAF 116/1119 reads (10%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- EPOP | c.105C>A p.F35L | Missense Mutation (SNP) | VAF 57/465 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- FAM110A | c.500G>T p.C167F | Missense Mutation (SNP) | VAF 38/139 reads (27%) | SIFT tolerated (0.67); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- FBN2 | c.7589G>C p.C2530S | Missense Mutation (SNP) | VAF 35/321 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- FCRL4 | c.448T>A p.W150R | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- FXN | c.386C>A p.A129D (on ENST00000377270; = p.A204D on NM_000144.5) | Missense Mutation (SNP) | VAF 30/453 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.667); called by muse, mutect2
- GDF7 | c.935C>A p.A312E | Missense Mutation (SNP) | VAF 72/629 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- H2BC11 | c.101G>T p.R34L | Missense Mutation (SNP) | VAF 22/413 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.582); called by muse, mutect2
- HOXD11 | c.214A>G p.K72E | Missense Mutation (SNP) | VAF 103/235 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- HPR | c.583A>G p.K195E | Missense Mutation (SNP) | VAF 89/344 reads (26%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- HS3ST3B1 | c.620C>T p.T207M | Missense Mutation (SNP) | VAF 40/242 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- HSD11B1L | c.19A>T p.T7S | Missense Mutation (SNP) | VAF 36/223 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- IGKV1D-43 | c.82C>A p.Q28K | Missense Mutation (SNP) | VAF 56/491 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- IGLV3-27 | c.286G>T p.A96S | Missense Mutation (SNP) | VAF 76/321 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.699); called by muse, mutect2, varscan2
- IRF3 | c.240C>G p.F80L | Missense Mutation (SNP) | VAF 96/496 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); called by muse, varscan2
- IRS2 | c.3313G>T p.V1105L | Missense Mutation (SNP) | VAF 30/138 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- ITGA7 | c.3032_3045del p.F1011Cfs*150 (on ENST00000555728; = p.F967Cfs*150 on NM_002206.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 102/591 reads (17%) | called by mutect2, pindel, varscan2
- ITGAD | c.778C>A p.Q260K | Missense Mutation (SNP) | VAF 14/125 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- JAK1 | c.1315G>A p.G439S | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.362); called by muse, mutect2, varscan2
- KISS1R | c.103C>T p.P35S | Missense Mutation (SNP) | VAF 72/437 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- L3MBTL3 | c.757G>C p.E253Q | Missense Mutation (SNP) | VAF 34/197 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.471); called by muse, mutect2
- LAMA5 | c.2343G>T p.R781S | Missense Mutation (SNP) | VAF 106/341 reads (31%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.523); called by muse, mutect2, varscan2
- LGI4 | c.746C>T p.S249F | Missense Mutation (SNP) | VAF 121/388 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- LHX1 | c.559A>G p.I187V | Missense Mutation (SNP) | VAF 106/460 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.683); called by muse, mutect2, varscan2
- LRFN2 | c.569A>T p.E190V | Missense Mutation (SNP) | VAF 48/620 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.665); called by muse, mutect2
- LYN | c.1115A>T p.N372I | Missense Mutation (SNP) | VAF 113/285 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MAD1L1 | c.1111G>T p.E371* | Nonsense Mutation (SNP) | VAF 33/210 reads (16%) | called by muse, mutect2, varscan2
- MALRD1 | c.3328C>G p.Q1110E | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT tolerated (0.51); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- MALRD1 | c.6029C>A p.A2010D | Missense Mutation (SNP) | VAF 74/317 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.473); called by muse, mutect2, varscan2
- MDC1 | c.1240C>A p.L414M | Missense Mutation (SNP) | VAF 30/209 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- MGA | c.862T>A p.S288T | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- MINDY2 | c.1126G>A p.D376N | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.47); PolyPhen benign (0.021); called by muse, varscan2
- MME | c.163G>C p.G55R | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- MS4A14 | c.673G>T p.G225C | Missense Mutation (SNP) | VAF 34/63 reads (54%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MUC19 | c.669+2T>C p.X223_splice | Splice Site (SNP) | VAF 53/191 reads (28%) | called by muse, mutect2, varscan2
- MUC3A | c.9207C>G p.F3069L | Missense Mutation (SNP) | VAF 39/958 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.866); called by muse, mutect2
- NAMPT | c.1175G>T p.R392I | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NID2 | c.14G>T p.R5L | Missense Mutation (SNP) | VAF 66/216 reads (31%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NINL | c.3731A>C p.Q1244P | Missense Mutation (SNP) | VAF 86/323 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NOX3 | c.1342G>T p.A448S | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.354); called by muse, mutect2, varscan2
- NPIPA5 | c.227A>G p.N76S | Missense Mutation (SNP) | VAF 76/579 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NPY2R | c.1012T>C p.S338P | Missense Mutation (SNP) | VAF 23/158 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- NUDT16L1 | c.274A>C p.T92P | Missense Mutation (SNP) | VAF 178/414 reads (43%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- OR10W1 | c.592A>G p.I198V | Missense Mutation (SNP) | VAF 156/273 reads (57%) | SIFT tolerated (0.13); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- OR2L3 | c.481T>G p.Y161D | Missense Mutation (SNP) | VAF 57/180 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- OR52K1 | c.707G>T p.R236L | Missense Mutation (SNP) | VAF 107/212 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.351); called by muse, mutect2, varscan2
- OR5AU1 | c.22C>T p.Q8* | Nonsense Mutation (SNP) | VAF 24/274 reads (9%) | called by muse, mutect2
- PCDH15 | c.5641G>T p.G1881C | Missense Mutation (SNP) | VAF 74/330 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PCDHGA5 | c.1330G>C p.D444H | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- PCDHGC5 | c.1952A>G p.N651S | Missense Mutation (SNP) | VAF 97/373 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.336); called by muse, mutect2, varscan2
- PDE3A | c.1736T>A p.L579Q | Missense Mutation (SNP) | VAF 15/295 reads (5%) | SIFT tolerated (0.29); PolyPhen benign (0.005); called by muse, mutect2
- PDPR | c.478A>T p.K160* | Nonsense Mutation (SNP) | VAF 106/453 reads (23%) | called by muse, mutect2, varscan2
- POTEH | c.319C>T p.P107S | Missense Mutation (SNP) | VAF 542/1694 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.641); called by muse, varscan2
- PPFIA3 | c.3267C>G p.I1089M | Missense Mutation (SNP) | VAF 48/190 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, varscan2
- PPM1B | c.932A>C p.E311A | Missense Mutation (SNP) | VAF 20/139 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- PRR36 | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 29/168 reads (17%) | SIFT deleterious, low confidence (0.01); called by muse, mutect2, varscan2
- PTPRM | c.3643G>A p.E1215K | Missense Mutation (SNP) | VAF 31/235 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- RAMP1 | c.154G>T p.G52W | Missense Mutation (SNP) | VAF 27/248 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RASGRF2 | c.1772G>C p.R591P | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- RBBP6 | c.3152G>A p.R1051K | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- RERGL | c.413G>T p.G138V | Missense Mutation (SNP) | VAF 53/182 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RGS2 | c.212+1G>T p.X71_splice | Splice Site (SNP) | VAF 90/298 reads (30%) | called by muse, mutect2, varscan2
- RIN3 | c.1159C>A p.P387T | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.406); called by muse, mutect2, varscan2
- RMI1 | c.1606G>A p.D536N | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- SEH1L | c.256T>C p.W86R | Missense Mutation (SNP) | VAF 29/246 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SEMA3E | c.1297C>G p.L433V | Missense Mutation (SNP) | VAF 29/210 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SLC25A23 | c.55G>T p.E19* | Nonsense Mutation (SNP) | VAF 43/333 reads (13%) | called by muse, mutect2, varscan2
- SLC7A14 | c.1477G>A p.E493K | Missense Mutation (SNP) | VAF 48/342 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- SLU7 | c.667G>C p.E223Q | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.784); called by mutect2, varscan2
- SNRPN | c.301G>A p.A101T | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.057); called by muse, mutect2
- SOX1 | c.586G>T p.V196L | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.015); called by muse, mutect2
- SUFU | c.1279C>G p.H427D | Missense Mutation (SNP) | VAF 129/515 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- TBC1D10A | c.989C>T p.T330I | Missense Mutation (SNP) | VAF 75/258 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- TET2 | c.1694_1697del p.I565Nfs*2 | Frame Shift Del (DEL) | VAF 43/176 reads (24%) | called by mutect2, pindel, varscan2
- TMEM108 | c.503C>T p.P168L | Missense Mutation (SNP) | VAF 71/524 reads (14%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TMEM44 | c.841G>T p.A281S (on ENST00000392432 / NM_001166305.2; = p.A234S on NM_138399.5) | Missense Mutation (SNP) | VAF 49/407 reads (12%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRHR | c.692C>G p.S231C | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.378); called by muse, mutect2, varscan2
- TRRAP | c.9668G>T p.C3223F (on ENST00000359863 / NM_001244580.1; = p.C3194F on NM_003496.3) | Missense Mutation (SNP) | VAF 34/326 reads (10%) | SIFT tolerated (0.46); PolyPhen benign (0.013); called by mutect2, varscan2
- TTC24 | c.211C>T p.Q71* | Nonsense Mutation (SNP) | VAF 33/247 reads (13%) | called by muse, mutect2, varscan2
- TTC6 | c.1622T>A p.I541N | Missense Mutation (SNP) | VAF 9/160 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.017); called by muse, mutect2
- TTN | c.10534G>A p.A3512T (on ENST00000591111; = p.A3466T on NM_003319.4) | Missense Mutation (SNP) | VAF 22/223 reads (10%) | called by muse, mutect2
- ULK3 | c.400T>G p.S134A | Missense Mutation (SNP) | VAF 38/200 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- USP9X | c.73C>T p.Q25* | Nonsense Mutation (SNP) | VAF 61/134 reads (46%) | called by muse, mutect2, varscan2
- VSIG10 | c.44G>A p.C15Y | Missense Mutation (SNP) | VAF 82/312 reads (26%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- YIPF5 | c.43A>T p.S15C | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.286); called by muse, mutect2, varscan2
- ZBTB49 | c.217_218delinsCAT p.S73Hfs*18 | Frame Shift Ins (INS) | VAF 10/39 reads (26%) | called by pindel, varscan2*
- ZEB2 | c.475C>A p.H159N | Missense Mutation (SNP) | VAF 16/183 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2
- ZNF735 | c.488T>C p.V163A | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.185); called by muse, varscan2
- ZNF804B | c.1835G>T p.G612V | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- ADCYAP1 | c.234C>G p.A78= | Silent (SNP) | VAF 58/130 reads (45%) | called by muse, mutect2, varscan2
- ADGRD1 | c.399G>C p.G133= | Silent (SNP) | VAF 69/276 reads (25%) | called by muse, mutect2, varscan2
- ADRA2A | c.597C>T p.A199= | Silent (SNP) | VAF 21/180 reads (12%) | called by muse, mutect2, varscan2
- ALPL | c.891C>T p.Y297= | Silent (SNP) | VAF 37/253 reads (15%) | catalogued as rs755529290, CM107629; called by muse, mutect2, varscan2
- ARSB | c.1590C>A p.G530= | Silent (SNP) | VAF 89/357 reads (25%) | called by muse, mutect2, varscan2
- C10orf71 | c.774C>G p.V258= | Silent (SNP) | VAF 18/196 reads (9%) | catalogued as COSV60510428; called by muse, mutect2
- CDK4 | c.261C>T p.I87= | Silent (SNP) | VAF 173/710 reads (24%) | catalogued as rs779482890; ClinVar: likely benign; called by muse, mutect2, varscan2
- CEP85L | c.459T>A p.L153= | Silent (SNP) | VAF 32/232 reads (14%) | called by muse, mutect2, varscan2
- CLDN18 | c.177C>T p.G59= | Silent (SNP) | VAF 37/549 reads (7%) | called by muse, mutect2
- CNGA4 | c.441G>A p.A147= | Silent (SNP) | VAF 44/291 reads (15%) | catalogued as rs767196089, COSV66005639; called by muse, mutect2, varscan2
- DAGLA | c.1803G>A p.P601= | Silent (SNP) | VAF 44/420 reads (10%) | catalogued as rs138378328; called by muse, mutect2, varscan2
- DOCK7 | c.6030A>C p.A2010= (on ENST00000635253 / NM_001367561.1; = p.A1979= on NM_033407.3) | Silent (SNP) | VAF 13/221 reads (6%) | catalogued as rs1227608019; called by muse, mutect2
- EPB41L3 | c.450C>T p.Y150= | Silent (SNP) | VAF 15/112 reads (13%) | catalogued as COSV59465326; called by muse, mutect2, varscan2
- FCGBP | c.5661C>G p.G1887= | Silent (SNP) | VAF 59/1453 reads (4%) | catalogued as COSV55438801; called by muse, mutect2
- FCRL5 | c.2520G>C p.L840= | Silent (SNP) | VAF 59/202 reads (29%) | called by muse, mutect2, varscan2
- FLG2 | c.5121C>T p.H1707= | Silent (SNP) | VAF 58/274 reads (21%) | called by muse, mutect2, varscan2
- FREM2 | c.9372C>T p.T3124= | Silent (SNP) | VAF 71/195 reads (36%) | called by muse, mutect2, varscan2
- GPR143 | c.60C>T p.L20= | Silent (SNP) | VAF 30/129 reads (23%) | catalogued as rs1202896647; called by muse, mutect2, varscan2
- GYS1 | c.1731G>A p.Q577= | Silent (SNP) | VAF 101/434 reads (23%) | called by muse, mutect2, varscan2
- HOXD11 | c.972G>A p.L324= | Silent (SNP) | VAF 37/254 reads (15%) | called by muse, mutect2, varscan2
- IFT88 | c.2217C>T p.G739= (on ENST00000319980 / NM_001318493.2; = p.G730= on NM_006531.5 and 9 other RefSeq transcripts) | Silent (SNP) | VAF 18/159 reads (11%) | called by muse, mutect2, varscan2
- IRF3 | c.822C>G p.L274= | Silent (SNP) | VAF 91/380 reads (24%) | called by muse, mutect2, varscan2
- LAMA3 | c.8124A>G p.V2708= (on ENST00000313654 / NM_198129.4; = p.V1099= on NM_000227.6) | Silent (SNP) | VAF 35/120 reads (29%) | called by muse, mutect2, varscan2
- LAMA5 | c.3507G>C p.S1169= | Silent (SNP) | VAF 41/370 reads (11%) | called by muse, mutect2, varscan2
- MEF2C | c.1296C>T p.D432= | Silent (SNP) | VAF 123/500 reads (25%) | catalogued as rs756839313, COSV60925026; called by muse, mutect2, varscan2
- MROH6 | c.1068C>T p.H356= | Silent (SNP) | VAF 70/818 reads (9%) | called by muse, mutect2
- MUC7 | c.1053T>A p.P351= | Silent (SNP) | VAF 24/161 reads (15%) | called by muse, mutect2, varscan2
- MYO16 | c.4740C>A p.P1580= | Silent (SNP) | VAF 7/23 reads (30%) | called by muse, mutect2, varscan2
- NOMO1 | c.1131C>A p.I377= | Silent (SNP) | VAF 71/462 reads (15%) | called by muse, mutect2, varscan2
- OR11H12 | c.540G>A p.Q180= | Silent (SNP) | VAF 104/625 reads (17%) | called by muse, mutect2, varscan2
- OR2C1 | c.382C>A p.R128= | Silent (SNP) | VAF 34/190 reads (18%) | called by muse, mutect2, varscan2
- OR4K14 | c.756T>C p.F252= | Silent (SNP) | VAF 42/214 reads (20%) | called by muse, mutect2, varscan2
- PARVG | c.357G>T p.L119= | Silent (SNP) | VAF 126/419 reads (30%) | called by muse, mutect2, varscan2
- PCDHA9 | c.1854G>C p.A618= | Silent (SNP) | VAF 178/679 reads (26%) | catalogued as COSV65325301; called by muse, mutect2, varscan2
- PCDHB2 | c.1743G>T p.A581= | Silent (SNP) | VAF 169/912 reads (19%) | catalogued as COSV99165054, COSV99165789; called by muse, mutect2, varscan2
- PPFIA3 | c.3315C>T p.S1105= | Silent (SNP) | VAF 86/452 reads (19%) | catalogued as rs747451020; called by muse, varscan2
- PPP2R2A | c.396A>G p.E132= | Silent (SNP) | VAF 17/41 reads (41%) | called by muse, mutect2, varscan2
- PRPS1 | c.948C>T p.V316= | Silent (SNP) | VAF 72/136 reads (53%) | called by muse, mutect2, varscan2
- RBKS | c.968G>A p.*323= | Silent (SNP) | VAF 46/88 reads (52%) | catalogued as COSV56087947; called by muse, varscan2
- RBM11 | c.105A>T p.P35= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as COSV68748076; called by mutect2, varscan2
- REELD1 | c.828G>A p.E276= | Silent (SNP) | VAF 114/339 reads (34%) | called by muse, mutect2, varscan2
- REG3A | c.504C>G p.P168= | Silent (SNP) | VAF 18/240 reads (8%) | called by muse, mutect2
- RPP38 | c.333G>A p.K111= | Silent (SNP) | VAF 17/248 reads (7%) | catalogued as rs991327887; called by muse, mutect2
- SCN5A | c.5439C>G p.V1813= (on ENST00000333535 / NM_198056.3; = p.V1812= on NM_000335.5) | Silent (SNP) | VAF 346/686 reads (50%) | called by muse, mutect2, varscan2
- SIGLEC16 | c.180G>A p.L60= | Silent (SNP) | VAF 106/702 reads (15%) | called by muse, mutect2, varscan2
- SNRNP200 | c.1944C>T p.L648= | Silent (SNP) | VAF 36/269 reads (13%) | catalogued as rs1054220177; called by muse, mutect2, varscan2
- TIGIT | c.492T>G p.T164= | Silent (SNP) | VAF 26/266 reads (10%) | called by muse, mutect2, varscan2
- TMPRSS9 | c.105C>A p.A35= | Silent (SNP) | VAF 72/195 reads (37%) | called by muse, mutect2, varscan2
- TNR | c.1582C>A p.R528= | Silent (SNP) | VAF 14/66 reads (21%) | catalogued as rs929965627, COSV54876364; called by muse, mutect2, varscan2
- TRAV39 | c.312C>T p.T104= | Silent (SNP) | VAF 34/151 reads (23%) | catalogued as rs1209428934; called by muse, mutect2, varscan2
- TRBV6-1 | c.27G>T p.V9= | Silent (SNP) | VAF 61/266 reads (23%) | called by muse, mutect2, varscan2
- TRIM47 | c.984C>T p.D328= | Silent (SNP) | VAF 46/180 reads (26%) | catalogued as rs1343649660; called by muse, mutect2, varscan2
- UNC5D | c.237A>T p.P79= | Silent (SNP) | VAF 75/461 reads (16%) | called by muse, mutect2, varscan2
- WDR97 | c.4752G>A p.P1584= | Silent (SNP) | VAF 10/310 reads (3%) | catalogued as rs1003056186; called by muse, mutect2
- ZNF382 | c.804T>C p.S268= | Silent (SNP) | VAF 6/51 reads (12%) | called by muse, mutect2, varscan2
- AGXT2 | c.*50G>C | 3'UTR (SNP) | VAF 17/82 reads (21%) | called by muse, mutect2, varscan2
- ANKRD26P1 | n.684A>C | RNA (SNP) | VAF 4/40 reads (10%) | called by muse, mutect2, varscan2
- APOBEC3B | c.1134+34C>T | Intron (SNP) | VAF 47/393 reads (12%) | catalogued as rs754228071; called by muse, mutect2, varscan2
- C11orf96 | chr11:43943396 C>A | 3'Flank (SNP) | VAF 104/167 reads (62%) | called by muse, mutect2, varscan2
- C8orf82 | c.156+285A>T | Intron (SNP) | VAF 54/129 reads (42%) | called by muse, mutect2, varscan2
- COQ5 | chr12:120529162 G>C | 5'Flank (SNP) | VAF 116/438 reads (26%) | catalogued as rs758489676; called by muse, mutect2, varscan2
- CORO1A | chr16:30183023 C>G | 5'Flank (SNP) | VAF 63/300 reads (21%) | catalogued as rs1003192913; called by muse, mutect2, varscan2
- CXCR2P1 | n.1025C>A | RNA (SNP) | VAF 103/264 reads (39%) | called by muse, mutect2, varscan2
- DNM1P46 | chr15:99808185 G>A | 5'Flank (SNP) | VAF 50/204 reads (25%) | catalogued as rs576239420; called by muse, mutect2, varscan2
- HAL | c.248-50del | Intron (DEL) | VAF 63/238 reads (26%) | called by mutect2, pindel, varscan2
- IQCN | c.2617-66G>A | Intron (SNP) | VAF 103/311 reads (33%) | catalogued as rs768923926; called by muse, mutect2, varscan2
- ITCH | c.1548-3703A>G | Intron (SNP) | VAF 10/35 reads (29%) | catalogued as rs1478026304, COSV52934936; called by muse, mutect2, varscan2
- KIF1B | c.2115+7127G>A | Intron (SNP) | VAF 26/138 reads (19%) | catalogued as rs764458505; called by muse, mutect2, varscan2
- LMNA | c.357-3711G>T | Intron (SNP) | VAF 43/145 reads (30%) | called by muse, varscan2
- LYZL1 | c.*1A>G | 3'UTR (SNP) | VAF 115/431 reads (27%) | catalogued as rs986116756; called by muse, mutect2, varscan2
- MICAL3 | c.-75+43331C>T | Intron (SNP) | VAF 17/185 reads (9%) | called by muse, mutect2
- MIR514A3 | n.53G>C | RNA (SNP) | VAF 23/107 reads (21%) | called by muse, mutect2, varscan2
- MST1L | n.951G>A | RNA (SNP) | VAF 71/566 reads (13%) | called by muse, mutect2, varscan2
- MYCBP2 | c.-18-123G>A | Intron (SNP) | VAF 20/145 reads (14%) | called by muse, mutect2, varscan2
- NT5DC2 | c.121+156G>A | Intron (SNP) | VAF 34/213 reads (16%) | called by muse, mutect2, varscan2
- OLFM2 | c.-44C>A | 5'UTR (SNP) | VAF 20/111 reads (18%) | catalogued as rs1393582708; called by muse, varscan2
- OPA1 | c.2983+1048C>T | Intron (SNP) | VAF 22/196 reads (11%) | called by muse, varscan2
- PIGK | c.-21G>C | 5'UTR (SNP) | VAF 62/485 reads (13%) | called by muse, mutect2, varscan2
- PNO1 | chr2:68157613 C>A | 5'Flank (SNP) | VAF 20/332 reads (6%) | called by muse, mutect2
- RAB3GAP2 | c.*27A>G | 3'UTR (SNP) | VAF 8/55 reads (15%) | called by muse, mutect2
- RPL22L1 | c.9+190A>G | Intron (SNP) | VAF 66/234 reads (28%) | called by muse, mutect2, varscan2
- SEC14L4 | c.*217C>T | 3'UTR (SNP) | VAF 62/276 reads (22%) | called by muse, mutect2, varscan2
- SMARCB1 | c.363-2063T>A | Intron (SNP) | VAF 180/736 reads (24%) | called by muse, mutect2, varscan2
- ST8SIA2 | chr15:92472474 G>T | 3'Flank (SNP) | VAF 4/18 reads (22%) | catalogued as rs1486150347; called by muse, mutect2
- TBC1D32 | c.*457A>T | 3'UTR (SNP) | VAF 20/53 reads (38%) | called by muse, mutect2, varscan2
- TMEM116 | c.-66-22383G>T | Intron (SNP) | VAF 29/112 reads (26%) | catalogued as rs759643136; called by muse, mutect2, varscan2
- TMPO | c.279+49G>C | Intron (SNP) | VAF 6/15 reads (40%) | called by muse, mutect2, varscan2
- TRIOBP | c.6324+196T>A | Intron (SNP) | VAF 225/863 reads (26%) | called by muse, mutect2, varscan2
- TSHR | c.692+181_692+189del | Intron (DEL) | VAF 60/530 reads (11%) | called by mutect2, pindel
- TSPAN31 | c.*1370A>C | 3'UTR (SNP) | VAF 24/362 reads (7%) | called by muse, mutect2
- VPS29 | c.3+595G>A | Intron (SNP) | VAF 82/363 reads (23%) | catalogued as rs1476885869; called by muse, mutect2, varscan2
- ZCWPW2 | c.658-3012G>A | Intron (SNP) | VAF 23/51 reads (45%) | called by muse, mutect2, varscan2
- ZNF252P | chr8:145003292 T>C | 5'Flank (SNP) | VAF 302/1020 reads (30%) | called by muse, mutect2, varscan2
